Gene-level copy-number profile of tumor specimen C3N-01653-03 from CPTAC case C3N-01653, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 58.4 years (21,323 days).
Specimen C3N-01653-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b12d5131-0340-4e91-bcd5-de5a492b20eb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01653-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/6e07f2ed-92ab-4af2-8a49-acf8a22f1251

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 11,323; copy number 2: 38,792; copy number 3: 5,606; copy number 4: 2,367; copy number 5: 337; copy number 6: 184; copy number 7: 31; copy number 8: 48; copy number 9: 65; copy number 10: 16; copy number 11: 39; copy number 12: 11; copy number 14: 6; copy number 15: 2; copy number 20: 22; copy number 21: 17; copy number 22: 1; copy number 25: 25.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:175,944,831–176,207,286, 1 gene (within-gene range 0–2): COP1.
- chr1:176,017,277–176,018,760, 1 gene: AL590723.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 804 genes in 33 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,573,801–248,601,869, 4 genes, copy number 5: OR2T34, OR2T10, Y_RNA, AC098483.2.
- chr2:31,865,060–32,157,637, 4 genes, copy number 5: MEMO1, DPY30, AL121655.1, SPAST.
- chr5:710,355–2,835,139, 55 genes, copy number 7–25: ZDHHC11B, BRD9P2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075, AC091849.2, SDHAP3, AC026412.3, AC091849.1, AC026412.1, AC026412.2, MIR4277, AC112176.1, MRPL36, NDUFS6, AC025183.1, LINC02116, AC025183.2, IRX4, IRX4-AS1, CTD-2194D22.4, AC126768.3, AC124852.1, AC126768.1, AC126768.2, Y_RNA, AC092266.1, LSINCT5, AC091891.1, IRX2, C5orf38, AC116359.1, AC094105.1.
- chr5:3,595,832–5,490,220, 27 genes, copy number 5–22: IRX1, AC016595.1, AC025773.1, AC025187.1, LINC02063, AC106799.3, AC106799.2, AC106799.1, AC010634.1, LINC02114, AC026719.1, AC026415.1, AC010451.3, AC010451.1, LINC01020, AC010451.2, LINC02121, RN7SKP73, CTD-2297D10.2, ADAMTS16, AC022424.1, ALG3P1, AC091978.1, MTCO1P30, MTCO2P30, MTCO1P31, ICE1.
- chr5:6,134,303–6,378,571, 4 genes, copy number 6: AC026797.1, HMGB3P3, LINC02145, MED10.
- chr5:6,633,427–6,833,120, 5 genes, copy number 6: SRD5A1, LINC02102, TENT4A, LINC02236, AC122710.2.
- chr5:6,848,127–6,888,087, 2 genes, copy number 6: RN7SKP79, AC122710.1.
- chr5:7,396,138–7,906,025, 5 genes, copy number 5: ADCY2, AC093305.1, C5orf49, MTRR, FASTKD3.
- chr5:13,637,919–13,638,381, 1 gene, copy number 8: AC016546.1.
- chr5:14,704,800–16,465,800, 24 genes, copy number 6: ANKH, AC010491.2, RBBP4P1, MIR4637, AC016575.1, UQCRBP3, HNRNPKP5, SEPHS2P1, U8, LINC02149, MARK2P5, AC114964.2, AC114964.1, FBXL7, CTD-2350J17.1, MIR887, RNA5SP178, MARCHF11, MARCHF11-AS1, AC092335.1, NACAP6, LINC02150, AC020980.1, ZNF622.
- chr5:30,365,405–30,365,684, 1 gene, copy number 6: AC114300.1.
- chr5:33,424,025–35,827,018, 36 genes, copy number 6–8: AC034231.1, TARS1, TOMM40P3, AC034232.1, ADAMTS12, RNU6-923P, RXFP3, SLC45A2, AC139783.2, AMACR, C1QTNF3-AMACR, AC139783.1, C1QTNF3, AC139792.2, AC139792.3, AC139792.1, AC138409.2, AC138409.1, AC138853.1, AC025754.2, RAI14, AC025754.1, AC026801.2, TTC23L, AC026801.1, RPL21P54, RAD1, BRIX1, DNAJC21, AGXT2, PRLR, AC010368.1, U3, SPEF2, RNU7-130P, AC137810.1.
- chr5:35,938,822–39,721,513, 66 genes, copy number 5–12 (broad region; genes not listed).
- chr5:45,254,948–45,895,970, 4 genes, copy number 5–7: HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr5:65,123,369–65,481,920, 4 genes, copy number 8 (within-gene range 3–8): Y_RNA, ADAMTS6, AC008868.1, RPEP1.
- chr5:69,280,175–70,448,015, 29 genes, copy number 8: CCDC125, CFL1P5, CHCHD2P2, NDUFB9P1, AK6, TAF9, RAD17, MARVELD2, RPS27P14, AC145146.1, RN7SL616P, OCLN, RNU6-724P, GTF2H2C, NAIPP3, AC139495.2, GUSBP3, AC139495.1, GUSBP13, AC131392.1, CDH12P2, SERF1B, SMN2, AC140134.1, NAIPP2, CDH12P3, AC138866.1, GUSBP14, GTF2H2B.
- chr5:78,485,215–81,852,201, 66 genes, copy number 7–11 (broad region; genes not listed).
- chr5:126,360,132–127,466,118, 22 genes, copy number 5: GRAMD2B, AC093535.1, AC093535.2, ALDH7A1, RNU6-290P, PHAX, AC099513.1, TEX43, BOLA3P3, HSPE1P10, LMNB1-DT, RNU6-752P, LMNB1, MARCHF3, C5orf63, AC005915.1, MRPS5P3, AC011416.1, SELENOTP2, AC011416.2, MEGF10, AC010424.1.
- chr5:132,481,609–132,490,777, 1 gene, copy number 5: IRF1.
- chr5:139,273,752–139,462,743, 17 genes, copy number 5 (within-gene range 3–5): MATR3, SNHG4, SNORA74D, SNORA74A, MATR3, RNA5SP195, RN7SKP64, PAIP2, AC135457.1, SLC23A1, MZB1, PROB1, SPATA24, DNAJC18, AC142391.1, RNU5B-4P, ECSCR.
- chr5:141,515,016–141,682,230, 8 genes, copy number 6: DIAPH1, DIAPH1-AS1, RPS27AP10, AC008781.1, HDAC3, RELL2, FCHSD1, ARAP3.
- chr5:157,142,933–157,255,185, 1 gene, copy number 9 (within-gene range 1–9): ITK.
- chr5:157,199,242–158,588,546, 36 genes, copy number 6–15: AC010609.1, AC009185.1, CYFIP2, AC008676.3, FNDC9, AC016571.1, AC008676.1, ADAM19, AC008676.2, NIPAL4, AC106801.1, RNU6-390P, AC008694.2, SOX30, C5orf52, AC008694.1, THG1L, LSM11, AC026407.1, CLINT1, RNU6-260P, AC008677.2, RNU2-48P, MARK2P11, AC008677.1, AC008677.3, AC025437.5, AC025437.4, AC025437.6, AC025437.3, AC025437.2, AC025437.1, LINC02227, AC091979.1, AC091979.2, AC091939.1.
- chr7:2,234,195–5,926,550, 73 genes, copy number 6–21 (within-gene range 4–21) (broad region; genes not listed).
- chr7:6,577,434–6,708,901, 8 genes, copy number 7: ZDHHC4, AC079742.1, C7orf26, ZNF853, ZNF316, AC073343.2, AC073343.1, ZNF12.
- chr7:10,449,820–10,779,944, 1 gene, copy number 9 (within-gene range 4–9): MGC4859.
- chr7:10,702,676–10,707,406, 1 gene, copy number 9: AC004415.1.
- chr7:11,180,902–11,520,175, 2 genes, copy number 7 (within-gene range 4–7): AC004160.1, NPM1P11.
- chr7:12,211,270–14,974,777, 24 genes, copy number 6 (within-gene range 3–6): TMEM106B, VWDE, AC013470.3, AC013470.2, SSBL5P, TAS2R2P, AC013470.1, AC005281.1, SCIN, AC011891.2, AC011891.3, ARL4A, AC011891.1, AC011287.1, RN7SKP228, RBMX2P4, AC011287.2, AC005019.2, AC005019.1, ETV1, Y_RNA, RPL6P21, DGKB, EEF1A1P26.
- chr16:1,972,053–7,713,340, 236 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr16:18,201,501–18,201,956, 1 gene, copy number 10: AC008785.1.
- chr16:33,769,421–34,163,110, 28 genes, copy number 5–6: ENPP7P13, AC136428.2, IGHV3OR16-12, AC136428.3, IGHV3OR16-13, AC136428.1, AC140658.6, AC140658.7, AC140658.2, IGHV3OR16-11, ARHGAP23P1, IGHV3OR16-7, AC140658.4, IGHV3OR16-16, AC140658.1, AC140658.5, AC133561.1, BCAP31P1, AC133561.2, AC133561.4, AC133561.3, AC136932.1, DUX4L45, PCMTD1P2, DUX4L46, DUX4L47, LINC00273, RNA5-8SP2.
- chr16:90,056,566–90,222,851, 8 genes, copy number 5: PRDM7, TUBB8P7, FAM157C, AC133919.1, AC133919.2, RNU6-355P, LINC02193, CICP25.

Autosomal genes at a single copy (total copy number 1): 8,480. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
